Somatic mutation profile of tumor specimen C3N-03424-03 (aliquot CPT0245780006) from CPTAC case C3N-03424, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.4 years (27,161 days).
Specimen C3N-03424-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e11836f3-8317-455d-b2f0-d04f726872f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03424-31 (Blood Derived Normal), aliquot CPT0245820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20ec37a2-31ab-47c9-8175-e0d568231001

The open-access MAF lists 245 somatic variants for this specimen: 166 protein-altering or splice-affecting, 43 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 43, Intron 15, RNA 12, Nonsense Mutation 12, 5'Flank 5, Splice Site 5, Frame Shift Del 3, 5'UTR 3, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as rs398124050, CM040026, COSV58905803; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 34/270 reads (13%) | hotspot (GDC flag); catalogued as COSV52676020, COSV52700231, COSV52728094, COSV52766542; called by muse, mutect2, varscan2
- ACTG1 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 30/590 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as rs1555667138; called by muse, mutect2
- ALDH1L1 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV56420021; called by muse, mutect2
- ALPG | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 46/696 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs765931067, COSV54965558; called by muse, mutect2
- ANK3 | c.10804C>T p.P3602S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV99780126; called by muse, mutect2
- AP1G1 | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV55485742; called by muse, mutect2
- APBB1 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 60/494 reads (12%) | catalogued as rs1290625702; called by muse, varscan2
- BCHE | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52253465, COSV52254588; called by muse, mutect2
- CCDC150 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.743); catalogued as rs1212840750; called by muse, mutect2
- CDH8 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV100181663, COSV54881609; called by muse, mutect2
- CEP250 | c.6659G>A p.R2220Q | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1241870345; called by muse, mutect2
- CLCNKA | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1230653852; called by muse, mutect2
- CNP | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.477); catalogued as rs998291648, COSV57268700; called by muse, mutect2
- CSF1 | c.1148C>G p.T383S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as rs752705819; called by muse, mutect2, varscan2
- DNAH1 | c.9929G>A p.G3310E | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761504421; called by muse, varscan2
- ELAVL4 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as rs776306356; called by muse, mutect2
- EML2 | c.1584T>A p.Y528* | Nonsense Mutation (SNP) | VAF 30/227 reads (13%) | catalogued as COSV55601973; called by muse, mutect2, varscan2
- FAM107B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); catalogued as COSV51683106, COSV51692349; called by muse, mutect2
- FAM135B | c.3805C>G p.Q1269E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99425947; called by muse, mutect2
- FAT3 | c.3581A>T p.N1194I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565383654, COSV53118407; called by muse, mutect2
- FREM2 | c.8668G>T p.E2890* | Nonsense Mutation (SNP) | VAF 18/372 reads (5%) | catalogued as COSV54831147; called by muse, mutect2
- FZD7 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs1438604237, COSV53808382, COSV53810943; called by muse, mutect2
- HEMGN | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99412566; called by muse, mutect2, varscan2
- HNF4A | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190126192, CM102625; called by muse, mutect2
- IGSF21 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs200305863, COSV52136122; called by muse, mutect2
- IRX1 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268978841; called by muse, mutect2
- KCNH8 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 32/230 reads (14%) | catalogued as COSV60477918; called by muse, mutect2, varscan2
- KCNQ4 | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.118); catalogued as CM1310603; called by muse, mutect2
- KDM7A | c.2357A>T p.D786V | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV50090071; called by muse, mutect2
- LRRTM1 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.053); catalogued as COSV54439698; called by muse, mutect2
- MAN1B1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs561918454; called by muse, mutect2, varscan2
- MAP3K7CL | c.549-2A>T p.X183_splice | Splice Site (SNP) | VAF 12/90 reads (13%) | catalogued as rs778788208; called by muse, varscan2
- MPP6 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs1389982904; called by muse, mutect2
- MRGPRE | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV67745684; called by muse, mutect2, varscan2
- MUC5AC | c.13928C>A p.S4643Y | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.07); catalogued as COSV100611293; called by muse, mutect2
- MYO3B | c.3874C>G p.P1292A | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV104397594; called by muse, mutect2, varscan2
- OR4A15 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 15/169 reads (9%) | catalogued as rs557771043; called by muse, mutect2
- OR4C13 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV73648743; called by muse, mutect2
- OR51B2 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1270756118; called by muse, mutect2, varscan2
- OR51L1 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.279); catalogued as COSV58624913; called by muse, mutect2
- OR8B4 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62070297; called by muse, mutect2, varscan2
- OR8I2 | c.86T>C p.L29S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV56169517; called by muse, varscan2
- PCDHA6 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 68/1012 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as COSV65343274; called by muse, mutect2
- PEG3 | c.4189C>G p.P1397A | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99690950; called by muse, mutect2, varscan2
- PHF8 | c.2027G>A p.R676Q (on ENST00000357988 / NM_001184896.1; = p.R640Q on NM_015107.3) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as rs782604120, COSV100153933, COSV57686975; called by muse, mutect2
- PIEZO2 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1409494922; called by muse, mutect2
- PLPPR3 | c.1060G>A p.V354M (on ENST00000520876 / NM_001270366.2; = p.V382M on NM_024888.2) | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100608599; called by muse, mutect2, varscan2
- POMT2 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 28/449 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.159); catalogued as COSV55073972; called by muse, mutect2
- RGR | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 23/422 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as rs983832204, COSV63893495; called by muse, mutect2
- RXRA | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100709219; called by muse, mutect2
- SALL2 | c.2189G>C p.G730A | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as rs1401016898; called by muse, mutect2
- SRCAP | c.2951C>G p.P984R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52670368; called by muse, mutect2
- SV2A | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs782202922; called by muse, mutect2, varscan2
- TEFM | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100035109; called by muse, mutect2
- TNK2 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 19/274 reads (7%) | catalogued as rs1007104079; called by muse, mutect2
- TONSL | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 49/346 reads (14%) | catalogued as rs910699280; called by muse, mutect2, varscan2
- TRA2B | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1167436888, COSV99373235; called by muse, mutect2
- UPB1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1260728563; called by muse, mutect2
- WDR62 | c.3842G>A p.R1281H | Missense Mutation (SNP) | VAF 62/367 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs371385084, COSV104373439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF416 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs1382042682; called by muse, mutect2
- ZNF420 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.446); catalogued as COSV58495919; called by muse, mutect2, varscan2
- ZNF596 | c.1471A>G p.R491G | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs1244339305; called by muse, mutect2
- ABCA9 | c.1748T>A p.F583Y | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2
- AC024598.1 | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- ACO1 | c.1961T>G p.L654W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2
- ACSF2 | c.288A>C p.E96D | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- ALG13 | c.1673C>A p.P558H | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- AMER2 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- APCDD1L | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ARHGAP22 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- ASTN1 | c.1626G>A p.M542I | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2
- ATCAY | c.1074-1G>A p.X358_splice | Splice Site (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- ATP1B4 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- C10orf71 | c.3683C>A p.P1228H | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CAMK4 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC85C | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 65/627 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CD3E | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- CDH26 | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 18/547 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDON | c.3313C>A p.P1105T | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); called by muse, mutect2
- CHRNB1 | c.439T>A p.Y147N | Missense Mutation (SNP) | VAF 89/603 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNR1 | c.1167C>A p.N389K | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CSMD3 | c.10552G>A p.V3518I (on ENST00000297405 / NM_001363185.1; = p.V3349I on NM_052900.3) | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- CSMD3 | c.4637C>A p.P1546H (on ENST00000297405 / NM_001363185.1; = p.P1442H on NM_052900.3) | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- CT47B1 | c.347_348insA p.A117Gfs*94 | Frame Shift Ins (INS) | VAF 66/354 reads (19%) | called by mutect2, pindel*, varscan2
- CYLC1 | c.1782del p.A595Qfs*73 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- DSCAM | c.934_934+4del p.X312_splice | Splice Site (DEL) | VAF 17/150 reads (11%) | called by mutect2, pindel, varscan2
- ECEL1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ELF5 | c.232G>C p.D78H (on ENST00000312319 / NM_198381.2; = p.D68H on NM_001422.4) | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- EML2 | c.1583A>T p.Y528F | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPHA10 | c.1157C>A p.A386E | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH6 | c.777C>A p.N259K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM71B | c.1418A>C p.H473P | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); called by muse, mutect2
- FAT3 | c.2180A>T p.K727M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN1 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- FBXL13 | c.1898A>G p.Y633C | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2
- FKBPL | c.472del p.E158Sfs*3 | Frame Shift Del (DEL) | VAF 31/272 reads (11%) | called by mutect2, varscan2
- FNIP1 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- GABRA1 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- GABRA6 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2
- GDF6 | c.1235C>G p.P412R | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRIN1 | c.1578G>C p.K526N | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GRAMD1C | c.1532G>A p.R511K | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GRM3 | c.297T>G p.C99W | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTPBP2 | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HEATR4 | c.2311A>C p.M771L | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- HNF4A | c.1232A>T p.H411L | Missense Mutation (SNP) | VAF 56/495 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTN3 | c.102+2T>C p.X34_splice | Splice Site (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- IQSEC3 | c.3502del p.L1168Cfs*51 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- IRX4 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); called by muse, mutect2
- JPH1 | c.1475C>A p.A492E | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLHL6 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- KMT2C | c.8520A>T p.E2840D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP10-3 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 97/737 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- LAMA1 | c.8460G>C p.M2820I | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2
- LDB2 | c.982T>A p.Y328N | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- LILRB3 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- LRP1B | c.11871G>T p.R3957S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2
- LRP1B | c.11870G>A p.R3957K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- LRRC10B | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, mutect2
- MLLT10 | c.2410C>A p.P804T (on ENST00000307729 / NM_001195626.3; = p.P820T on NM_004641.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MTMR14 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.7120G>T p.E2374* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2
- NEFL | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- NELFCD | c.1678C>T p.Q560* (on ENST00000602795; = p.Q542* on NM_198976.4) | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- NUFIP2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- OR10AG1 | c.725T>A p.F242Y | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2
- OR5K4 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PATL1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- PCDH1 | c.2617C>G p.L873V | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.05); called by muse, mutect2
- PCDHGA5 | c.1780G>T p.V594L | Missense Mutation (SNP) | VAF 66/461 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PEX1 | c.1418C>G p.S473C | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIWIL1 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2
- PKP1 | c.2134T>C p.W712R | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLPPR3 | c.1511G>C p.G504A (on ENST00000520876 / NM_001270366.2; = p.G532A on NM_024888.2) | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEA | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.216); called by muse, mutect2
- POU3F3 | c.626T>C p.M209T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTER | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRN2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- RASA1 | c.1934+1G>T p.X645_splice | Splice Site (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- SAMD9 | c.4127G>A p.C1376Y | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SCAPER | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.286); called by muse, mutect2
- SCN11A | c.3271A>T p.N1091Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2
- SELENOW | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEPTIN3 | c.866T>A p.V289E | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SI | c.2912C>A p.A971E | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2
- SLC41A2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLITRK2 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNTG2 | c.438T>A p.D146E | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2
- SPAG1 | c.2569C>G p.L857V | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SPATA31A6 | c.1288A>T p.N430Y | Missense Mutation (SNP) | VAF 51/582 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- SPATA31D4 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SPCS3 | c.306A>T p.Q102H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTBN4 | c.4471A>T p.N1491Y | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SUGCT | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); called by muse, mutect2
- TJP2 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- TLL2 | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM132C | c.1818C>A p.F606L | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- TMEM150C | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- TOPAZ1 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2
- TTYH1 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- UBXN4 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- URAD | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- USH2A | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF850 | c.1499C>A p.T500N | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZYG11B | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ASIC2 | c.372G>A p.P124= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs770764384, COSV63332185; called by muse, mutect2
- ATP2A2 | c.96T>G p.L32= | Silent (SNP) | VAF 16/177 reads (9%) | called by muse, mutect2, varscan2
- C7orf26 | c.1023C>T p.A341= | Silent (SNP) | VAF 17/187 reads (9%) | catalogued as rs769603866; called by muse, mutect2
- CC2D1B | c.1023G>A p.L341= | Silent (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- CELA2A | c.390C>A p.P130= | Silent (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- CHD6 | c.6138G>T p.G2046= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- DEAF1 | c.1461C>T p.A487= | Silent (SNP) | VAF 28/448 reads (6%) | called by muse, mutect2
- DNAAF3 | c.996G>T p.G332= (on ENST00000524407 / NM_001256715.2; = p.G379= on NM_178837.4) | Silent (SNP) | VAF 28/511 reads (5%) | called by muse, mutect2
- FAM189A1 | c.1056T>C p.G352= | Silent (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- FAM71B | c.202C>A p.R68= | Silent (SNP) | VAF 27/294 reads (9%) | called by muse, mutect2
- FGB | c.684T>C p.T228= | Silent (SNP) | VAF 29/186 reads (16%) | called by muse, mutect2, varscan2
- FOXL1 | c.870C>G p.G290= | Silent (SNP) | VAF 24/278 reads (9%) | catalogued as COSV57214787; called by muse, mutect2
- GPR37 | c.1305C>G p.A435= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1119C>G p.V373= | Silent (SNP) | VAF 17/253 reads (7%) | called by muse, mutect2
- KLHL1 | c.1662T>A p.P554= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- LRRTM1 | c.1293C>T p.G431= | Silent (SNP) | VAF 19/219 reads (9%) | catalogued as rs761157979; called by muse, mutect2
- MAP2 | c.2133C>A p.S711= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- MTR | c.1734C>T p.S578= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- NID1 | c.2964G>A p.V988= | Silent (SNP) | VAF 21/299 reads (7%) | called by muse, mutect2
- NPHS2 | c.156G>A p.G52= | Silent (SNP) | VAF 25/254 reads (10%) | called by muse, mutect2, varscan2
- OGDHL | c.915G>C p.L305= | Silent (SNP) | VAF 28/331 reads (8%) | catalogued as rs753867652; called by muse, mutect2
- PCBP1 | c.183G>C p.L61= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- PCDH17 | c.1461G>T p.P487= | Silent (SNP) | VAF 19/339 reads (6%) | catalogued as COSV64978142; called by muse, mutect2
- PGC | c.465C>A p.V155= | Silent (SNP) | VAF 22/239 reads (9%) | called by muse, mutect2
- PLEKHG4B | c.2940C>T p.H980= (on ENST00000283426; = p.H1336= on NM_052909.5) | Silent (SNP) | VAF 29/208 reads (14%) | catalogued as rs769273622, COSV52052314; called by muse, mutect2, varscan2
- PLXNA4 | c.4389T>C p.C1463= | Silent (SNP) | VAF 31/270 reads (11%) | called by muse, mutect2, varscan2
- PPM1G | c.15C>G p.L5= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as rs1283578659; called by muse, mutect2
- PTPRJ | c.324G>A p.G108= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1405865319; called by muse, mutect2
- RPTN | c.1029T>C p.Y343= | Silent (SNP) | VAF 41/404 reads (10%) | catalogued as rs1557824509, COSV60167896; called by muse, mutect2, varscan2
- SAP30L | c.456G>A p.V152= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- SH3D19 | c.1860C>T p.F620= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV100456026; called by muse, mutect2
- SHANK2 | c.2979G>C p.G993= | Silent (SNP) | VAF 40/815 reads (5%) | called by muse, mutect2
- SLC16A12 | c.270C>A p.I90= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- SOX17 | c.1176C>T p.H392= | Silent (SNP) | VAF 32/442 reads (7%) | catalogued as rs771488614, COSV52027339; called by muse, mutect2
- SOX9 | c.150G>A p.E50= | Silent (SNP) | VAF 24/351 reads (7%) | catalogued as rs1240920173, COSV55422277, COSV55429260; called by muse, mutect2
- STRN | c.1215T>A p.S405= | Silent (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- TGM6 | c.882C>T p.V294= | Silent (SNP) | VAF 42/320 reads (13%) | catalogued as rs762965769, COSV52482870; called by muse, mutect2, varscan2
- TINAGL1 | c.1158G>T p.V386= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- TRIM49B | c.123C>G p.L41= | Silent (SNP) | VAF 18/405 reads (4%) | called by muse, mutect2
- TSSK2 | c.135C>T p.R45= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as rs1322126750; called by muse, mutect2, varscan2
- USH2A | c.10782G>A p.L3594= | Silent (SNP) | VAF 15/253 reads (6%) | catalogued as rs771265408; called by muse, mutect2
- USP6 | c.1803C>G p.A601= | Silent (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- VWA8 | c.3273A>G p.E1091= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- ABI2 | c.118-15280G>C | Intron (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- AC010542.3 | c.149-11984T>A | Intron (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- AC136759.1 | n.1249T>C | RNA (SNP) | VAF 26/359 reads (7%) | catalogued as rs1245588701; called by muse, mutect2
- ANKRD42 | chr11:83194457 C>T | 5'Flank (SNP) | VAF 33/231 reads (14%) | called by muse, mutect2, varscan2
- AP3B2 | c.2441-30C>A | Intron (SNP) | VAF 24/380 reads (6%) | called by muse, mutect2
- ATL3 | chr11:63671406 C>A | 5'Flank (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- CDHR1 | c.863-43C>A | Intron (SNP) | VAF 35/263 reads (13%) | called by muse, mutect2, varscan2
- DCHS2 | n.2431T>C | RNA (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- DEFB121 | n.174G>T | RNA (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- EPDR1 | c.-211G>A | 5'UTR (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- EYS | c.1767-7274G>A | Intron (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- FAM153CP | n.587del | RNA (DEL) | VAF 22/188 reads (12%) | called by mutect2, varscan2
- HBE1 | c.-267+74682T>G | Intron (SNP) | VAF 22/357 reads (6%) | called by muse, mutect2
- HSD17B7P2 | n.240T>C | RNA (SNP) | VAF 22/443 reads (5%) | called by muse, mutect2
- IMP4 | c.112+132A>T | Intron (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2848-1422G>T | Intron (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- LAD1 | c.39-1797C>T | Intron (SNP) | VAF 7/166 reads (4%) | catalogued as rs1051999260; called by muse, mutect2
- LAMA1 | c.1156-46G>T | Intron (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2
- LINC01193 | n.840C>A | RNA (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- MIR216B | n.39T>A | RNA (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- MIR518A1 | n.31T>A | RNA (SNP) | VAF 41/175 reads (23%) | called by muse, mutect2, varscan2
- NARF | c.521-222C>T | Intron (SNP) | VAF 9/154 reads (6%) | catalogued as rs1438300722; called by muse, mutect2
- NELL2 | c.56-179A>G | Intron (SNP) | VAF 28/311 reads (9%) | catalogued as rs750065539; called by muse, mutect2
- OVCH1-AS1 | n.389G>T | RNA (SNP) | VAF 21/380 reads (6%) | called by muse, mutect2
- PDGFRA | c.*7G>T | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by mutect2, varscan2
- RNPS1 | chr16:2271772 del GCGGGGCC | 5'Flank (DEL) | VAF 30/252 reads (12%) | called by mutect2, pindel
- SDHAP2 | n.1829A>C | RNA (SNP) | VAF 62/712 reads (9%) | called by muse, mutect2
- SENP2 | chr3:185582696 G>T | 5'Flank (SNP) | VAF 23/385 reads (6%) | called by muse, mutect2
- SYCE1 | chr10:133567988 G>T | 5'Flank (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- TAZ | c.584-44C>T | Intron (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.1015G>A | RNA (SNP) | VAF 29/496 reads (6%) | called by muse, mutect2
- TOMM5 | c.121+25G>T | Intron (SNP) | VAF 38/362 reads (10%) | called by muse, mutect2, varscan2
- WAS | c.-46C>A | 5'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- ZNF140 | c.232+9909C>T | Intron (SNP) | VAF 13/189 reads (7%) | catalogued as rs1341380478; called by muse, mutect2
- ZNF841 | c.-94G>T | 5'UTR (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- ZNF849P | n.1064C>T | RNA (SNP) | VAF 19/231 reads (8%) | called by muse, mutect2
